Somatic mutation profile of tumor specimen TCGA-EE-A2M7-06A (aliquot TCGA-EE-A2M7-06A-11D-A197-08) from TCGA case TCGA-EE-A2M7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.9 years (25,166 days).
Specimen TCGA-EE-A2M7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eec386d3-5da5-4879-8f98-542fbb36627d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2M7-10A (Blood Derived Normal), aliquot TCGA-EE-A2M7-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45830a84-d3ae-4faa-9cca-7c827f8f087e

The open-access MAF lists 71 somatic variants for this specimen: 41 protein-altering or splice-affecting, 25 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 25, Nonsense Mutation 2, Intron 2, 5'Flank 1, Splice Site 1, RNA 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/106 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- HMGCS2 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 58/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28937320, CM032942, COSV65567695; ClinVar: pathogenic; called by mutect2, varscan2
- APC | c.4616C>T p.S1539L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as CM106377, CM970093, COSV57338178, COSV57338685, COSV57338819; called by mutect2, varscan2
- ATP5F1A | c.88T>G p.F30V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99959259; called by muse, mutect2, varscan2
- CDH12 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs375209667, COSV101203473; called by muse, varscan2
- CDKL3 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54741028; called by muse, mutect2, varscan2
- CLVS1 | c.237T>G p.F79L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57973426; called by muse, mutect2
- COL5A2 | c.3793G>A p.D1265N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100880073, COSV66408805; called by muse, mutect2, varscan2
- CRX | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55757867; called by muse, mutect2, varscan2
- CYP4F11 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs138578304; called by muse, varscan2
- EGFR | c.791G>A p.C264Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51790699; called by mutect2, varscan2
- FAF2 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56130610; called by muse, varscan2
- FAF2 | c.1092C>G p.I364M | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56130623; called by muse, varscan2
- GRM8 | c.1673T>C p.L558P | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV58818684; called by muse, mutect2, varscan2
- HEATR6 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1402375766, COSV51744874; called by mutect2, varscan2
- HEPACAM | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 28/126 reads (22%) | catalogued as COSV53429066; called by muse, mutect2, varscan2
- HERC2 | c.11899G>C p.G3967R | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55318385; called by muse, mutect2, varscan2
- MGAM | c.5068G>A p.D1690N | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV72074436; called by muse, mutect2, varscan2
- MROH2B | c.3114G>T p.Q1038H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV101270978; called by mutect2, varscan2
- OR1E2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50265539; called by muse, mutect2, varscan2
- OR6C4 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.291); catalogued as COSV67792891; called by mutect2, varscan2
- PLEKHM1 | c.150G>A p.M50I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV69598707; called by mutect2, varscan2
- PRSS27 | c.641G>A p.C214Y | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57013189; called by mutect2, varscan2
- PTPN18 | c.280G>C p.G94R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51558652; called by muse, mutect2, varscan2
- RNASE3 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58959335; called by muse, varscan2
- RTKN | c.1093C>T p.R365* (on ENST00000272430 / NM_001015055.2; = p.R352* on NM_033046.2) | Nonsense Mutation (SNP) | VAF 27/174 reads (16%) | catalogued as rs199677316; called by muse, varscan2
- SETD1A | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs760563687, COSV52686790; called by muse, mutect2, varscan2
- SGSM1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs573738280, COSV68509850; called by mutect2, varscan2
- SIRT4 | c.892C>A p.L298M | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV52540613; called by mutect2, varscan2
- SLC5A1 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV56684720; called by muse, mutect2, varscan2
- SLC7A11 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV54929643; called by mutect2, varscan2
- SLIT3 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60603242; called by mutect2, varscan2
- TENM1 | c.5855G>A p.R1952Q | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs201279168, COSV64429887; called by muse, mutect2, varscan2
- TGFB3 | c.646+1G>A p.X216_splice | Splice Site (SNP) | VAF 18/104 reads (17%) | catalogued as COSV53169326; called by muse, mutect2, varscan2
- TSNAXIP1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV54649346; called by mutect2, varscan2
- TTN | c.15653C>A p.A5218E (on ENST00000591111; = p.A4291E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | PolyPhen possibly damaging (0.678); catalogued as COSV59989915; called by muse, mutect2, varscan2
- WDR41 | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV56998390; called by mutect2, varscan2
- ZNF536 | c.3418C>A p.H1140N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.01); catalogued as COSV62822413; called by mutect2, varscan2
- ZNF676 | c.877G>A p.G293R (on ENST00000650058; = p.G261R on NM_001001411.3) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV68092784, COSV68093468; called by muse, mutect2, varscan2
- ZNF99 | c.2417A>T p.K806I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.885); catalogued as COSV68055453; called by mutect2, varscan2
- CPD | c.2263_2264del p.N755Lfs*3 | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | called by mutect2, pindel, varscan2
- ANPEP | c.1239C>T p.F413= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs373066082; called by mutect2, varscan2
- CLMP | c.636C>T p.N212= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs185664299, COSV71649591; called by mutect2, varscan2
- DYNLRB1 | c.208C>A p.R70= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV55963693, COSV55963925; called by muse, mutect2, varscan2
- GRIN2B | c.2823C>T p.F941= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as rs369299730; called by muse, mutect2, varscan2
- HLA-B | c.771C>G p.T257= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV69521032; called by muse, mutect2, varscan2
- IFNA21 | c.561G>A p.R187= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV66518204, COSV66518299; called by muse, mutect2, varscan2
- IL31RA | c.1539G>A p.L513= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV51681092; called by muse, mutect2, varscan2
- KCND2 | c.252C>T p.F84= | Silent (SNP) | VAF 22/183 reads (12%) | catalogued as rs1282232580, COSV58576379, COSV58585770; called by muse, mutect2, varscan2
- MAGI1 | c.3744C>A p.P1248= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV58322171; called by muse, mutect2, varscan2
- MAN2B1 | c.1605C>T p.F535= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs1421304561, COSV55471383; called by mutect2, varscan2
- MGA | c.5409C>T p.H1803= (on ENST00000219905 / NM_001164273.1; = p.H1594= on NM_001080541.2) | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs768321882, COSV54952042; called by muse, mutect2, varscan2
- MRGPRX4 | c.546G>A p.A182= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as rs200576638, COSV58590317; called by mutect2, varscan2
- MYOM1 | c.3258G>A p.Q1086= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs776698468, COSV55289644; called by muse, mutect2, varscan2
- NFX1 | c.1911C>T p.F637= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV59308389, COSV59309568; called by muse, mutect2, varscan2
- NLRP7 | c.2457C>T p.F819= (on ENST00000340844 / NM_206828.3; = p.F791= on NM_139176.3) | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs201605286, COSV60171548; called by muse, mutect2, varscan2
- OR52N1 | c.558G>T p.V186= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV57693210; called by muse, mutect2, varscan2
- SCN2A | c.3981A>G p.V1327= | Silent (SNP) | VAF 21/172 reads (12%) | catalogued as COSV51838103; called by muse, mutect2, varscan2
- SLC17A1 | c.720C>A p.S240= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV99766274; called by mutect2, varscan2
- STAU2 | c.930C>T p.S310= (on ENST00000524300 / NM_001164380.2; = p.S278= on NM_014393.2) | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs1263316426, COSV63307711; called by muse, mutect2, varscan2
- TAF1L | c.3927G>A p.S1309= | Silent (SNP) | VAF 80/216 reads (37%) | catalogued as rs776454125, COSV54260539; called by muse, mutect2, varscan2
- TNC | c.1992G>T p.L664= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV60783551; called by mutect2, varscan2
- TRPM2 | c.2772C>T p.I924= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as COSV55968466; called by muse, varscan2
- ZNF208 | c.3474T>C p.Y1158= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV68103674; called by muse, varscan2
- ZNF333 | c.147C>T p.P49= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs569763417, COSV52885577; called by muse, mutect2, varscan2
- ZNF423 | c.636C>A p.S212= (on ENST00000563137 / NM_001379286.1; = p.S204= on NM_015069.4) | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV52184755, COSV52199011; called by mutect2, varscan2
- C15orf54 | n.894A>G | RNA (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- PNKD | c.236+1169C>A | Intron (SNP) | VAF 67/233 reads (29%) | catalogued as COSV99298204; called by muse, mutect2, varscan2
- SUCO | chr1:172532483 T>G | 5'Flank (SNP) | VAF 7/46 reads (15%) | catalogued as COSV55270322, COSV99742904, COSV99744253; called by muse, mutect2, varscan2
- UNC119 | c.610+17T>C | Intron (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99971844; called by muse, mutect2, varscan2
- ZNF99 | c.*852G>A | 3'UTR (SNP) | VAF 13/30 reads (43%) | catalogued as COSV101233878, COSV101234006; called by muse, mutect2, varscan2
